Somatic mutation profile of tumor specimen TARGET-20-PASHBI-09A (aliquot TARGET-20-PASHBI-09A-01D) from TARGET case TARGET-20-PASHBI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.7 years (5,727 days).
Specimen TARGET-20-PASHBI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09aa29a3-c30c-40a7-901c-bef54f2a2891.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASHBI-14A (Bone Marrow Normal), aliquot TARGET-20-PASHBI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cc874e8-f093-4b9f-9704-22b13ffcd2bc

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 3, Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLLT10 | c.2014C>A p.R672S (on ENST00000307729 / NM_001195626.3; = p.R688S on NM_004641.3) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.144); catalogued as rs148827631, COSV57001251; called by muse, mutect2, varscan2
- WT1 | c.1338_1339insGGGA p.K447Gfs*19 | Frame Shift Ins (INS) | VAF 31/98 reads (32%) | catalogued as COSV60068878, COSV60084004, COSV99070046, COSV99070049; called by mutect2, pindel, varscan2
- WT1 | c.1074dup p.V359Cfs*14 | Frame Shift Ins (INS) | VAF 25/134 reads (19%) | catalogued as COSV60068321, COSV60085606, COSV60086731; called by mutect2, pindel, varscan2
- CBL | c.1505_1506insGGTGACCT p.L503Vfs*115 | Frame Shift Ins (INS) | VAF 57/82 reads (70%) | called by mutect2, pindel, varscan2
- AMER1 | c.*850G>T | 3'UTR (SNP) | VAF 73/107 reads (68%) | called by muse, mutect2, varscan2
